Somatic mutation profile of tumor specimen 0DNJBN from CCDI case PBCBTF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,397 days).
Specimen 0DNJBN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd59b986-3815-47f9-911e-069d21ef8a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNJA8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cef3788b-6b1c-4a71-b58b-04758850971c

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOM3 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 32/560 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs758030227, COSV100294103; called by muse, mutect2
- PRSS16 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 87/458 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs773835973, COSV57915867; called by muse, varscan2
- DAPK1 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 196/889 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2
- PKIA | c.114A>C p.L38F | Missense Mutation (SNP) | VAF 25/572 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2
- JADE3 | c.90G>A p.K30= | Silent (SNP) | VAF 214/769 reads (28%) | called by muse, mutect2, varscan2
- KIF17 | c.2781C>T p.G927= | Silent (SNP) | VAF 192/774 reads (25%) | catalogued as rs752090322; called by muse, mutect2, varscan2
- RALB | c.477G>A p.A159= | Silent (SNP) | VAF 166/676 reads (25%) | catalogued as rs146299608; called by muse, mutect2, varscan2
- ADAD2 | c.*99G>C | 3'UTR (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2
